Somatic mutation profile of tumor specimen MP2PRT-PATGTW-TMP1-A (aliquot MP2PRT-PATGTW-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATGTW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,491 days).
Specimen MP2PRT-PATGTW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eef5206e-01f9-4eac-a05d-5778fe058aab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATGTW-NM1-B (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATGTW-NM1-B-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/965030ea-d1b0-4011-a0e7-e6502b93dd68

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 9, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1, 5'Flank 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1E | c.2171A>C p.N724T | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV62435223; called by muse, mutect2, varscan2
- CSMD3 | c.9074G>A p.R3025H (on ENST00000297405 / NM_001363185.1; = p.R2856H on NM_052900.3) | Missense Mutation (SNP) | VAF 159/431 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs199604170, COSV52182215; called by muse, mutect2, varscan2
- EYS | c.1541T>G p.V514G | Missense Mutation (SNP) | VAF 15/481 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1259593345; called by muse, mutect2
- JAML | c.874C>G p.L292V (on ENST00000356289 / NM_001098526.2; = p.L282V on NM_153206.3) | Missense Mutation (SNP) | VAF 51/400 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52629811; called by muse, mutect2, varscan2
- MCCC1 | c.398C>G p.S133* | Nonsense Mutation (SNP) | VAF 28/273 reads (10%) | catalogued as COSV55610217, COSV99659967; called by muse, mutect2
- PARD3B | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753773435, COSV62505771, COSV62511639; called by muse, mutect2, varscan2
- PDZRN4 | c.2765G>A p.R922Q (on ENST00000402685 / NM_001164595.2; = p.R664Q on NM_013377.4) | Missense Mutation (SNP) | VAF 139/401 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207064397, COSV100114802, COSV54221611; called by muse, mutect2, varscan2
- PLXNA3 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 33/769 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1557203606; called by muse, mutect2
- SMG8 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 54/622 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.355); catalogued as rs1270615398; called by muse, mutect2
- SYDE2 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 24/376 reads (6%) | catalogued as rs768611054, COSV52318935; called by muse, mutect2
- ZSCAN21 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 39/612 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.419); catalogued as rs1295388935; called by muse, mutect2
- ADCY8 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 49/376 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- ANK1 | c.5014C>G p.L1672V | Missense Mutation (SNP) | VAF 18/428 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.05); called by muse, mutect2
- BAIAP2L2 | c.896C>G p.S299W | Missense Mutation (SNP) | VAF 79/522 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- DNAAF4 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- EPB41L3 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 52/492 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- HIPK3 | c.650G>C p.R217T | Missense Mutation (SNP) | VAF 18/546 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.195); called by muse, mutect2
- IFT172 | c.1623G>C p.Q541H | Missense Mutation (SNP) | VAF 52/492 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV5-51 | chr14:106578742 TGTCTCGCACAGTAATACAT>GTTCGAGG | Missense Mutation (DEL) | VAF 10/87 reads (11%) | called by pindel, varscan2*
- IGKV2-28 | chr2:89221690 ACTGTGGGAGGAGTTTGTAGAG>CGT | Missense Mutation (DEL) | VAF 85/166 reads (51%) | called by pindel, varscan2*
- IRX5 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 28/574 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2
- LAMA1 | c.940A>G p.R314G | Missense Mutation (SNP) | VAF 136/374 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- LGI2 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 132/347 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- MKS1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 13/346 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MZF1 | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 58/696 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- NEDD4L | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- NELL2 | c.1461C>G p.I487M | Missense Mutation (SNP) | VAF 11/346 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.119); called by muse, mutect2
- NLRP5 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 55/486 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- OR5AP2 | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 37/457 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- PCSK1 | c.586C>G p.P196A | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDX1 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 50/874 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.937); called by muse, mutect2
- PEBP4 | c.381G>C p.K127N | Missense Mutation (SNP) | VAF 41/406 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SLC35G6 | c.425C>G p.S142C | Missense Mutation (SNP) | VAF 40/704 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SMG8 | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 64/542 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TENM3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 24/602 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.025); called by muse, mutect2
- TRGV5 | c.353_354insCCCG p.R118Sfs*? | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | called by mutect2, pindel*, varscan2*
- ANK2 | c.10512C>T p.D3504= | Silent (SNP) | VAF 15/537 reads (3%) | catalogued as rs1162076185; called by muse, mutect2
- CEP152 | c.2112C>A p.L704= | Silent (SNP) | VAF 15/533 reads (3%) | catalogued as COSV57864676; called by muse, mutect2
- DACT1 | c.2073G>C p.L691= | Silent (SNP) | VAF 254/772 reads (33%) | catalogued as COSV60023485; called by muse, mutect2, varscan2
- ENG | c.1806C>T p.I602= | Silent (SNP) | VAF 37/610 reads (6%) | catalogued as rs373002544; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- KCNT1 | c.3204G>A p.T1068= (on ENST00000488444; = p.T1094= on NM_020822.3) | Silent (SNP) | VAF 34/806 reads (4%) | catalogued as rs754919919; ClinVar: likely benign; called by muse, mutect2
- NBEA | c.6132C>T p.L2044= | Silent (SNP) | VAF 24/420 reads (6%) | catalogued as rs749281887, COSV100078866, COSV100081381; called by muse, mutect2
- SLC22A15 | c.981G>C p.L327= | Silent (SNP) | VAF 26/496 reads (5%) | called by muse, mutect2
- SLC35G6 | c.426C>T p.S142= | Silent (SNP) | VAF 40/701 reads (6%) | catalogued as rs563869962, COSV59496844; called by muse, mutect2
- YJEFN3 | c.888C>T p.V296= | Silent (SNP) | VAF 16/486 reads (3%) | catalogued as rs1355087427; called by muse, mutect2
- AC092718.9 | chr16:81148302 G>C | 5'Flank (SNP) | VAF 100/341 reads (29%) | called by muse, mutect2, varscan2
- DMWD | c.*560del | 3'UTR (DEL) | VAF 85/319 reads (27%) | called by pindel*, varscan2
- NPAP1L | n.994C>T | RNA (SNP) | VAF 87/283 reads (31%) | catalogued as rs200010991, COSV73747706; called by muse, mutect2, varscan2
- SLC22A31 | c.-165C>T | 5'UTR (SNP) | VAF 34/599 reads (6%) | called by muse, mutect2
